Somatic mutation profile of tumor specimen TCGA-23-1022-01A (aliquot TCGA-23-1022-01A-02W-0488-09) from TCGA case TCGA-23-1022, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.9 years (24,798 days).
Specimen TCGA-23-1022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c06cbcef-103e-4d03-a358-be17063c7abe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1022-10A (Blood Derived Normal), aliquot TCGA-23-1022-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c0a1121-0113-4e76-a109-e23db502a8e9

The open-access MAF lists 217 somatic variants for this specimen: 171 protein-altering or splice-affecting, 44 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 44, Nonsense Mutation 8, Frame Shift Del 7, In Frame Del 2, Frame Shift Ins 2, Splice Region 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3359G>A p.G1120E | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as rs28933379, COSV57359343, COSV57363821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HEXA | c.1305C>T p.Y435= | Silent (SNP) | VAF 378/515 reads (73%) | catalogued as rs587779406, CS102998, COSV51507879; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 109/116 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.1060C>T p.Q354* (on ENST00000372530 / NM_001198934.2; = p.Q311* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55087429, COSV55092062; called by muse, mutect2, varscan2
- ABCC9 | c.2571A>T p.K857N | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV99683892; called by muse, mutect2
- ABRA | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV61733178, COSV61733580; called by muse, mutect2, varscan2
- ACAA2 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53270773, COSV53271749; called by muse, mutect2, varscan2
- ACOT9 | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV60538564; called by muse, mutect2, varscan2
- ACSM4 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 196/455 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68068822; called by muse, mutect2, varscan2
- ADCY3 | c.2190C>A p.Y730* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53170751; called by muse, mutect2, varscan2
- ADGRD1 | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV55452429; called by muse, mutect2, varscan2
- ADGRG7 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs765888895, COSV56293266; called by muse, mutect2, varscan2
- ADGRL3 | c.985T>A p.S329T (on ENST00000506720 / NM_001322402.2; = p.S261T on NM_015236.6) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.138); catalogued as rs972384097, COSV72270421; called by muse, mutect2, varscan2
- ADORA2B | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs762496834, COSV58482853, COSV58483601; called by muse, mutect2, varscan2
- AIFM3 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100104055; called by muse, mutect2
- AKAP6 | c.6536C>G p.S2179C | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.237); catalogued as COSV104384199, COSV55225758; called by muse, mutect2
- ALPK3 | c.2872G>C p.D958H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51937408; called by muse, mutect2, varscan2
- AOC1 | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781356994, COSV62870139; called by muse, mutect2, varscan2
- APC | c.6014C>G p.S2005* | Nonsense Mutation (SNP) | VAF 75/155 reads (48%) | catalogued as COSV57366916; called by muse, mutect2, varscan2
- ARHGAP30 | c.2329C>G p.Q777E | Missense Mutation (SNP) | VAF 154/685 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs770292771, COSV63518275; called by muse, mutect2, varscan2
- ASNS | c.1464C>G p.Y488* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV51554603; called by muse, mutect2, varscan2
- ASNSD1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV53624471; called by muse, mutect2
- B9D2 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV54684592; called by muse, mutect2, varscan2
- BMPER | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as COSV51827211; called by muse, mutect2, varscan2
- BOLA1 | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.157); catalogued as COSV64967444; called by muse, mutect2
- C12orf29 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467473; called by muse, mutect2
- C1QTNF1 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV59263311; called by muse, mutect2, varscan2
- C2CD3 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58090296, COSV58097566; called by muse, mutect2, varscan2
- C2CD5 | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV61726535; called by muse, mutect2, varscan2
- CAPS2 | c.1584A>C p.K528N | Missense Mutation (SNP) | VAF 72/359 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV60827717; called by muse, mutect2, varscan2
- CELF1 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60114278; called by muse, mutect2, varscan2
- CEMIP2 | c.1549G>T p.G517W | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100987185, COSV65486214; called by muse, mutect2
- CHRM2 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV57779984; called by muse, varscan2
- CHST9 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 138/466 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52445240; called by muse, mutect2, varscan2
- COL11A2 | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.941); catalogued as COSV59500480; called by muse, mutect2, varscan2
- COL16A1 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV54711289; called by muse, mutect2, varscan2
- COL1A2 | c.2809G>A p.G937S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM070783, COSV51961112, COSV51963189; called by muse, mutect2, varscan2
- COL9A1 | c.28T>A p.F10I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.009); catalogued as COSV61835809; called by muse, mutect2, varscan2
- COPB2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs560518160, COSV60350829; called by muse, mutect2, varscan2
- CSRP2 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV60703182; called by muse, mutect2, varscan2
- CUL5 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV67609772; called by muse, mutect2
- CYP4F12 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV61175543; called by muse, mutect2, varscan2
- DEFB114 | c.64A>T p.T22S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV59038345; called by muse, mutect2, varscan2
- DENND2A | c.928T>G p.S310A | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV52056161; called by muse, mutect2, varscan2
- DOC2A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1487993007, COSV58752258; called by muse, mutect2, varscan2
- ENC1 | c.1039G>C p.G347R | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56628604, COSV56630588; called by muse, mutect2, varscan2
- ENPP1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1370913047, COSV62934810; called by muse, mutect2, varscan2
- ERBB4 | c.3113G>A p.R1038K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV61510771; called by muse, mutect2
- ESR1 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV52793878, COSV99237102; called by muse, mutect2
- FAM120B | c.2713_2714insT p.D905Vfs*102 | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | catalogued as COSV53006876; called by mutect2, pindel, varscan2
- FAM135B | c.4175T>C p.F1392S | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52713244; called by muse, mutect2, varscan2
- FAM187B | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV61201578; called by muse, mutect2, varscan2
- FAT3 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.52); catalogued as rs765974517, COSV53152547; called by muse, mutect2, varscan2
- FBXO24 | c.279G>C p.Q93H (on ENST00000241071 / NM_033506.3; = p.Q131H on NM_012172.5) | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53828416; called by muse, mutect2, varscan2
- FOCAD | c.2374G>T p.G792W | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105081; called by muse, mutect2, varscan2
- FOXI1 | c.78dup p.E27Rfs*7 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs776996183; called by pindel, varscan2
- FREM2 | c.5888T>C p.I1963T | Missense Mutation (SNP) | VAF 103/153 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs753924671, COSV54846299; called by muse, mutect2, varscan2
- FSIP1 | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs997415836, COSV63226195; called by muse, mutect2, varscan2
- GJA8 | c.1169A>G p.K390R | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53789935; called by muse, mutect2, varscan2
- GLIS3 | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV100173017; called by muse, mutect2
- GM2A | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV100852020; called by muse, mutect2
- GPR55 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV67408281; called by muse, mutect2, varscan2
- HCN4 | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086026; called by muse, mutect2, varscan2
- HEATR5A | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV66343974; called by muse, mutect2, varscan2
- HECTD4 | c.11771G>A p.C3924Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV66396846; called by muse, mutect2
- HECW2 | c.179G>A p.S60N | Missense Mutation (SNP) | VAF 67/388 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53669140; called by muse, mutect2, varscan2
- HK2 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877971; called by muse, mutect2, varscan2
- HSPG2 | c.2410A>G p.M804V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65975052; called by muse, mutect2, varscan2
- HYDIN | c.6587C>G p.P2196R | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV59265487, COSV59275502; called by muse, mutect2, varscan2
- INA | c.1297A>C p.S433R | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV63976361; called by muse, mutect2, varscan2
- JADE3 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99509419; called by muse, mutect2
- KIF24 | c.3821G>A p.C1274Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV52660623; called by muse, mutect2, varscan2
- KLHL6 | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58068437; called by muse, mutect2, varscan2
- KLK3 | c.234C>A p.H78Q | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58102015; called by muse, mutect2, varscan2
- LIMS1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 17/159 reads (11%) | catalogued as COSV100185299, COSV57539833; called by muse, mutect2, varscan2
- LMNA | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as CM135989, COSV61543641; called by muse, mutect2, varscan2
- LMNTD1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 87/374 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV51449374, COSV99280000; called by muse, mutect2, varscan2
- LPAR4 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.677); catalogued as rs372050796, COSV70913115, COSV70913491; called by muse, mutect2, varscan2
- LRCH4 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.086); catalogued as COSV59644054; called by muse, mutect2, varscan2
- LTBP1 | c.3730G>A p.D1244N (on ENST00000404816 / NM_206943.4; = p.D918N on NM_000627.4) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55383190; called by muse, mutect2, varscan2
- MANEA | c.173A>T p.N58I | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62590268; called by muse, mutect2, varscan2
- MATN2 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV54716555; called by muse, mutect2, varscan2
- MNDA | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV63741692; called by muse, mutect2, varscan2
- MTA3 | c.1525+8G>T | Splice Region (SNP) | VAF 24/87 reads (28%) | catalogued as COSV63196946; called by muse, varscan2
- MTCL1 | c.2705C>A p.P902H (on ENST00000306329 / NM_001378206.1; = p.P542H on NM_015210.4) | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60409680; called by muse, mutect2, varscan2
- MUC17 | c.9295A>T p.T3099S | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV60297975; called by muse, mutect2, varscan2
- MYH4 | c.3721A>T p.T1241S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99700059; called by muse, mutect2
- NLRP12 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.152); catalogued as COSV60744103; called by muse, mutect2, varscan2
- NLRP13 | c.1212A>T p.E404D | Missense Mutation (SNP) | VAF 135/266 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV61620193, COSV61623429; called by muse, mutect2, varscan2
- NNMT | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV55474561; called by muse, mutect2, varscan2
- NPAS2 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.03); catalogued as COSV59556413; called by muse, mutect2, varscan2
- NR1D2 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 10/185 reads (5%) | catalogued as COSV100437232; called by muse, mutect2
- NRAP | c.3659C>A p.P1220H (on ENST00000359988 / NM_001322945.2; = p.P1185H on NM_006175.4) | Missense Mutation (SNP) | VAF 141/246 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63492876; called by muse, mutect2, varscan2
- NUMBL | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248524795, COSV53284286, COSV99424748; called by muse, mutect2, varscan2
- NXN | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as rs1013992060, COSV61098965; called by muse, mutect2, varscan2
- OR4D6 | c.860A>C p.Y287S | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55660574; called by muse, mutect2, varscan2
- OR4N2 | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60053664; called by muse, mutect2, varscan2
- OR5H1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 22/688 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as rs1328068502, COSV100641577; called by muse, mutect2
- OR7D2 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 161/585 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV60140746; called by muse, mutect2, varscan2
- OR8U1 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 268/572 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56414498; called by muse, varscan2
- PAX7 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64751771; called by muse, mutect2, varscan2
- PCDHB15 | c.1566G>C p.E522D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51217442; called by muse, mutect2, varscan2
- PIK3C2A | c.1200C>G p.H400Q | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56405408; called by muse, mutect2, varscan2
- PKHD1L1 | c.11698del p.L3900Ffs*38 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | catalogued as COSV101006731; called by mutect2, pindel, varscan2
- PLA2G6 | c.2114G>A p.C705Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV59272332; called by muse, mutect2, varscan2
- PLXNC1 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 114/407 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs533262461, COSV51573002; called by muse, mutect2, varscan2
- PPBP | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV56020102; called by muse, mutect2, varscan2
- PPFIA4 | c.3094T>A p.W1032R (on ENST00000447715; = p.W1033R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55319418; called by muse, mutect2, varscan2
- PPP1R17 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs777370118, COSV59612130; called by muse, mutect2, varscan2
- PRMT5 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756575000, COSV99362694; called by muse, mutect2
- PROS1 | c.1610T>G p.V537G | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV101260104; called by muse, mutect2
- PSD4 | c.1611C>G p.H537Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV55528798; called by muse, mutect2, varscan2
- PSMD3 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV52857920; called by muse, mutect2, varscan2
- PTGIS | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.245); catalogued as COSV54839366; called by muse, mutect2, varscan2
- PYHIN1 | c.1190A>T p.Q397L | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV63723529; called by muse, mutect2, varscan2
- RANBP6 | c.317A>G p.K106R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52390801; called by muse, mutect2, varscan2
- RASGEF1C | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs755415164, COSV63179542; called by muse, mutect2, varscan2
- RGL4 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV51944916; called by muse, mutect2, varscan2
- RIMS4 | c.666G>C p.E222D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV65720382; called by muse, mutect2, varscan2
- RNF111 | c.2768A>T p.K923I (on ENST00000557998 / NM_001270530.1; = p.K915I on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62088659; called by muse, mutect2, varscan2
- RNF112 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV71326997; called by muse, mutect2, varscan2
- RORB | c.434A>G p.N145S (on ENST00000396204 / NM_001365023.1; = p.N134S on NM_006914.4) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV65338638; called by muse, mutect2, varscan2
- RRAGD | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.674); catalogued as rs1165142740, COSV63269904; called by muse, mutect2, varscan2
- RXRB | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV59500485; called by muse, mutect2, varscan2
- RYR1 | c.8843C>G p.S2948W | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs759514075, COSV62105299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.8807C>G p.A2936G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV63703400; called by muse, mutect2, varscan2
- S1PR3 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs764521861, COSV63980385, COSV63981148; called by muse, varscan2
- SACS | c.4145A>G p.H1382R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs550057119, COSV66544758; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCGB2A2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs779171446, COSV57174834; called by muse, mutect2, varscan2
- SCLY | c.806A>T p.Y269F (on ENST00000651534; = p.Y261F on NM_016510.7) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54543189; called by muse, mutect2, varscan2
- SCN8A | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1359860813, COSV61988866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL2 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV62570064; called by muse, mutect2, varscan2
- SH3TC2 | c.3134A>T p.E1045V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60466214; called by muse, mutect2, varscan2
- SHC1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as COSV58316642; called by muse, mutect2, varscan2
- SIGLEC8 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58475111; called by muse, mutect2, varscan2
- SLC16A11 | c.1259G>T p.S420I (on ENST00000308009; = p.S396I on NM_153357.3) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1037010388, COSV57274753; called by muse, mutect2, varscan2
- SLC9C2 | c.1689G>C p.M563I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62947882; called by muse, mutect2, varscan2
- ST8SIA6 | c.800T>G p.L267R | Missense Mutation (SNP) | VAF 54/529 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66470587; called by muse, mutect2, varscan2
- STAB2 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66343962; called by muse, mutect2, varscan2
- STK38L | c.206A>C p.Q69P | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV101198682; called by muse, mutect2
- TAF6 | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV59842877; called by muse, mutect2, varscan2
- TDG | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378394461, COSV57167852; called by muse, mutect2, varscan2
- TENM4 | c.5324G>A p.G1775D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53654333; called by muse, mutect2, varscan2
- TIAM1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54565684; called by muse, mutect2, varscan2
- TNF | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV69305182; called by muse, mutect2, varscan2
- TRIP4 | c.618+1G>T p.X206_splice | Splice Site (SNP) | VAF 41/96 reads (43%) | catalogued as COSV56032331; called by muse, mutect2, varscan2
- UGGT1 | c.1246A>G p.N416D | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.034); catalogued as COSV52139564; called by muse, mutect2, varscan2
- UMOD | c.1667C>G p.A556G | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV56778119; called by muse, mutect2, varscan2
- USH2A | c.5731G>A p.G1911R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56409873; called by muse, mutect2, varscan2
- UST | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV66549197; called by muse, mutect2, varscan2
- WBP2NL | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV60920451; called by muse, mutect2, varscan2
- WDTC1 | c.1990G>A p.D664N (on ENST00000319394 / NM_001276252.2; = p.D663N on NM_015023.5) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs138646253; called by muse, mutect2, varscan2
- XKR3 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as COSV58887397; called by muse, mutect2, varscan2
- XPO6 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV58969512; called by muse, mutect2, varscan2
- ZBTB20 | c.2086C>A p.P696T (on ENST00000474710 / NM_001164342.2; = p.P623T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV61861693; called by muse, mutect2, varscan2
- ZFP37 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1414705430, COSV65288055; called by muse, mutect2, varscan2
- ZNF583 | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 47/315 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV52400968, COSV52404032; called by muse, mutect2, varscan2
- ZNF91 | c.2825A>C p.E942A | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs762775014, COSV56089627; called by muse, mutect2, varscan2
- ZSCAN20 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755926539, COSV63683928; called by muse, mutect2, varscan2
- ZXDC | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs1244248729, COSV60447989; called by muse, mutect2, varscan2
- ADRB2 | c.1053del p.N352Mfs*91 | Frame Shift Del (DEL) | VAF 39/86 reads (45%) | called by mutect2, varscan2
- ASPM | c.2254_2272del p.S752Lfs*5 | Frame Shift Del (DEL) | VAF 31/217 reads (14%) | called by mutect2, pindel, varscan2
- COL11A2 | c.1193_1205del p.E398Afs*8 (on ENST00000341947 / NM_080680.3; = p.E291Afs*8 on NM_080679.2) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- EID3 | c.779_804del p.F260Wfs*8 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- HPGDS | c.161del p.L54Wfs*12 | Frame Shift Del (DEL) | VAF 56/84 reads (67%) | called by mutect2, pindel, varscan2
- KIAA0319 | c.2705T>A p.L902H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFATC2 | c.1681_1682del p.Q561Dfs*4 | Frame Shift Del (DEL) | VAF 27/202 reads (13%) | called by pindel*, varscan2
- OTOA | c.865A>C p.N289H | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POMGNT1 | c.795_797del p.R267del | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by pindel, varscan2
- PSD4 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- RBM41 | c.1114G>T p.G372* | Nonsense Mutation (SNP) | VAF 10/349 reads (3%) | called by muse, mutect2
- SARS2 | c.195_218del p.C66_A73del | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS19 | c.3144G>A p.A1048= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs754047149, COSV50774614, COSV99176695; called by muse, mutect2, varscan2
- AHNAK | c.17511G>A p.E5837= | Silent (SNP) | VAF 24/760 reads (3%) | catalogued as COSV99945072; called by muse, mutect2
- BCOR | c.4101C>T p.H1367= (on ENST00000378444 / NM_001123385.2; = p.H1333= on NM_017745.6) | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60706365; called by muse, mutect2, varscan2
- BMP3 | c.450A>G p.G150= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV51091576; called by muse, mutect2, varscan2
- BRINP2 | c.432T>A p.T144= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV100837776; called by muse, mutect2
- BRSK1 | c.582C>A p.P194= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as COSV58668724; called by mutect2, varscan2
- CBLL1 | c.90C>T p.L30= | Silent (SNP) | VAF 52/204 reads (25%) | catalogued as COSV56029998; called by muse, mutect2, varscan2
- CCDC88C | c.3225G>C p.L1075= | Silent (SNP) | VAF 23/24 reads (96%) | catalogued as COSV66240276; called by muse, mutect2, varscan2
- CEP290 | c.5916T>C p.D1972= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as COSV58354340; called by muse, mutect2, varscan2
- EFCAB12 | c.72C>T p.P24= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV58177959; called by muse, mutect2, varscan2
- EIF4G1 | c.2679G>T p.R893= (on ENST00000346169 / NM_198241.3; = p.R698= on NM_004953.5) | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV59992734; called by muse, mutect2, varscan2
- EVA1C | c.1032A>G p.R344= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV55825881; called by muse, mutect2, varscan2
- FAT1 | c.7062G>A p.R2354= | Silent (SNP) | VAF 49/57 reads (86%) | catalogued as rs756397442, COSV71674973; called by muse, mutect2, varscan2
- GABBR1 | c.1383A>T p.T461= | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as COSV100589352; called by muse, mutect2
- GABRG2 | c.495C>A p.T165= | Silent (SNP) | VAF 79/203 reads (39%) | catalogued as COSV62720788; called by muse, mutect2, varscan2
- GLDN | c.669C>T p.S223= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV59091610; called by muse, mutect2, varscan2
- HELQ | c.3138C>G p.L1046= | Silent (SNP) | VAF 90/228 reads (39%) | catalogued as rs768787457, COSV55026412, COSV55026723; called by muse, mutect2, varscan2
- IQCA1 | c.714G>T p.L238= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- KCNH1 | c.2199G>A p.P733= (on ENST00000271751 / NM_172362.3; = p.P706= on NM_002238.4) | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs756120939, COSV55079432; called by muse, mutect2, varscan2
- LIMS1 | c.60T>C p.A20= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV100185296; called by muse, mutect2, varscan2
- LMTK2 | c.4374G>A p.T1458= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs542059077, COSV51990095; called by muse, varscan2
- LRRC39 | c.825C>T p.F275= | Silent (SNP) | VAF 96/188 reads (51%) | catalogued as COSV61583636; called by muse, mutect2, varscan2
- MYH14 | c.5394C>G p.A1798= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV51827129; called by muse, mutect2, varscan2
- MYH7 | c.4761G>A p.K1587= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV100805531; called by muse, mutect2
- OR13H1 | c.441C>A p.T147= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as COSV100088080; called by muse, mutect2
- OR5AS1 | c.837T>G p.T279= | Silent (SNP) | VAF 58/234 reads (25%) | catalogued as COSV57982705; called by muse, mutect2, varscan2
- PAX4 | c.693C>G p.L231= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV58390288; called by muse, mutect2, varscan2
- PCDH1 | c.2520G>C p.G840= | Silent (SNP) | VAF 85/179 reads (47%) | catalogued as COSV54617684; called by muse, mutect2, varscan2
- PCDHB6 | c.483C>G p.T161= | Silent (SNP) | VAF 13/221 reads (6%) | catalogued as COSV99171480; called by muse, mutect2
- PCDHB7 | c.1737G>A p.A579= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs567529552, COSV50797976; called by muse, mutect2, varscan2
- PIAS1 | c.477C>T p.D159= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1308624111, COSV51035736; called by muse, mutect2, varscan2
- PRAMEF1 | c.892T>C p.L298= | Silent (SNP) | VAF 31/818 reads (4%) | catalogued as COSV100179309, COSV60010135; called by muse, mutect2
- PTPRN | c.1731G>C p.V577= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV55350706; called by muse, mutect2, varscan2
- RIMS4 | c.667C>T p.L223= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs764339672, COSV65720380; called by muse, mutect2, varscan2
- SERPINA12 | c.438A>G p.P146= | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as COSV100369529; called by muse, mutect2
- SHARPIN | c.1086C>T p.A362= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV59644822; called by muse, mutect2, varscan2
- SPTA1 | c.6975T>G p.A2325= | Silent (SNP) | VAF 129/311 reads (41%) | catalogued as COSV63757293; called by muse, mutect2, varscan2
- TEX47 | c.342T>C p.Y114= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as COSV51879610, COSV51879791, COSV99787243; called by muse, mutect2, varscan2
- TTN | c.50844C>A p.G16948= (on ENST00000591111; = p.G9524= on NM_003319.4) | Silent (SNP) | VAF 51/275 reads (19%) | catalogued as COSV60237556; called by muse, mutect2, varscan2
- WNT2 | c.768T>A p.A256= | Silent (SNP) | VAF 111/459 reads (24%) | catalogued as COSV55412731; called by muse, mutect2, varscan2
- ZNF324B | c.894G>C p.S298= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100351838, COSV60742768; called by muse, mutect2, varscan2
- ZNF333 | c.1077C>A p.I359= | Silent (SNP) | VAF 28/523 reads (5%) | catalogued as COSV99468650; called by muse, mutect2
- ZNF613 | c.1753T>C p.L585= (on ENST00000293471 / NM_001031721.4; = p.L549= on NM_024840.4) | Silent (SNP) | VAF 25/146 reads (17%) | catalogued as rs1000726756, COSV53273195; called by muse, mutect2, varscan2
- MIR518A2 | n.23G>T | RNA (SNP) | VAF 105/490 reads (21%) | called by muse, mutect2, varscan2
- ODF2 | c.1911+21G>T | Intron (SNP) | VAF 19/75 reads (25%) | catalogued as COSV63548329; called by muse, mutect2, varscan2
